Surgical pathology report (de-identified scan), TCGA case TCGA-UY-A78L, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of California San Francisco, specimen TCGA-UY-A78L-01A (Primary Tumor).

[page 1 of 4]
ICD-O-3
Carcinoma, urothelial
papillary 8130/3
Site Bladder NOS
C67.9
JW 8/20/13

FINAL PATHOLOGIC DIAGNOSIS

- A. Left distal ureter, margin, biopsy: No tumor identified.
- B. Right distal ureter, margin, biopsy: No tumor identified.
- C. Urethra, margin, biopsy: No tumor identified.
- D. Lymph nodes, left pelvic, dissection: Metastatic carcinoma in one of eleven lymph nodes (1/11).
- E. Urinary bladder and prostate, cystoprostatectomy: *Per TSS, adenocarcinoma 5?*
- 1. High-grade urothelial carcinoma, mixed transitional cell and adenocarcinoma *see* types, with deep invasion into muscularis propria, no extension into periurithral fat; see comment.
- 2. Papillary urothelial hyperplasia of trigone.
- 3. Small focus of urothelial carcinoma in situ in urinary outflow tract of bladder.
- 4. Benign prostatic tissue, distal prostatic urethra free of tumor.
- F. Lymph nodes, right pelvic, dissection: No tumor identified in twelve lymph nodes (0/12).
- G. Lymph nodes, right pelvic, biopsy: No tumor identified.
- H. Left ureter, biopsy: No tumor identified.
- I. Right ureter, biopsy: No tumor identified.

[page 2 of 4]
COMMENT:

Bladder Tumor Synoptic Comment

1. Tumor type: Urothelial carcinoma with partial glandular differentiation.
2. Tumor grade: High grade.
3. Tumor size: 3 cm.
4. Extent of tumor in bladder: Invasion into outer half of muscularis propria, but not beyond.
5. Lymphatic/vascular invasion: None identified.
6. Epithelial abnormalities in bladder: Carcinoma in situ.
7. Extension of tumor into organs adjacent to bladder: No adjacent organs involved.
8. Surgical margins:
- Urethral margin: Free of tumor.
- Right ureter margin: Free of tumor.
- Left ureter margin: Free of tumor.
- Perivesical margin: Free of tumor.
9. Lymph nodes: One of twenty-three (1/23) lymph nodes contain metastatic tumor; the largest metastatic deposit measures 0.7 cm in greatest dimension; there is no extranodal tumor growth.
10. Other pathologic findings in bladder: Papillary urothelial hyperplasia.
11. AJCC/UICC stage: pT2bN1Mx.
-

Specimen(s) Received

- A: Left distal uretral margin (FS)
- B: Right distal uretral margin (FS)
- C: Urethral margin (FS)
- D: Left pelvic nodes (FS)
- E: Bladder & prostate (FS)
- F: Right pelvic lymph nodes (FS)
- G: Right pelvic lymph node
- H: Final left ureter
- I: Final right ureter

Intraoperative Diagnosis

- FS1 (A) Left distal ureter margin, biopsy: No carcinoma identified. [REDACTED]
- FS2 (B) Right distal ureter margin, biopsy: No carcinoma identified. [REDACTED]
- FS3 (C) Urethral margin, biopsy: No carcinoma identified. Benign prostatic glands noted. [REDACTED]
- FS4 (D) Left pelvic lymph node, excision: No carcinoma identified (0/3). [REDACTED]
- FS5 (E) Bladder and prostate, distal urethral margin, biopsy: No carcinoma identified. [REDACTED]
- FS6 (F) Right pelvic lymph nodes, dissection: No carcinoma identified (0/3). [REDACTED]

Clinical History

The patient is a [REDACTED]-year-old man with bladder tumor.

Gross Description

The specimen is received in nine parts, each labeled with the patient's name and medical record number. Parts A through F are received fresh, and Parts G through I are received in formalin.

Part A is additionally labeled "left distal ureteral margin." It consists of a donut-shaped fragment of tan-pink tissue, measuring 1.0 x 0.2 x 0.2 cm. The specimen is entirely submitted for frozen section diagnosis as FS1, with the frozen section remnant submitted in cassette A1.

[page 3 of 4]
Part B is additionally labeled "right distal ureteral margin." It consists of a fragment of tan-pink tissue, measuring 0.7 cm in diameter with a lumen in the center. The specimen is entirely submitted for frozen section diagnosis as FS2, with the frozen section remnant submitted in cassette B1.

Part C is additionally labeled "urethral margin." It consists of multiple fragments of red-tan tissue, measuring 1.0 x 0.9 x 0.4 cm in aggregate. The specimen is entirely submitted for frozen section diagnosis as FS3, with the frozen section remnant submitted in cassette C1.

Part D is additionally labeled "left pelvic lymph nodes." It consists of multiple fragments of fibroadipose tissue, measuring 5.0 x 5.0 x 1.5 cm in aggregate. Dissection reveals multiple tan-pink, soft lymph nodes, ranging from 0.3 cm to 0.8 cm. Representative sections are submitted for frozen section diagnosis as FS4, with the frozen section remnant submitted in cassette D1. Additional lymph nodes are dissected from the adipose tissue and are submitted in cassettes D2 and D3.

Part E is additionally labeled "bladder, prostate, distal urethral margin." It consists of a cystoprostatectomy specimen, weighing 275 gm and measuring 17.0 x 9.5 x 4.5 cm. The specimen is inked as follows: the right-anterior surface is inked green, the left-anterior surface is inked blue, and the posterior surface is inked black. The ureters are probed and are patent. The specimen is opened along its anterior edge through the prostatic urethra. The urinary bladder measures 9.0 x 7.0 x 5.0 cm, and the prostate measures 4.0 x 3.0 x 3.0 cm. On opening, there is a large tumor, measuring 3.0 x 2.0 x 1.5 cm, in the left posterior-lateral surface of the urinary bladder. The region of the trigone shows mucosal swelling and irregularity in an area measuring 2.5 x 2.5 cm. No other gross lesions are noted. The ureters grossly appear to be free of tumor. On serial sectioning of the prostate, no tumor is noted. The seminal vesicles are unremarkable. On the cut surface, the prostatic parenchyma is tan-white and is firm in appearance. Representative sections are submitted as follows:

Cassette E1:	Distal urethral margin.
Cassette E2:	Right ureteral margin.
Cassette E3:	Left ureteral margin.
Cassettes E4-E7:	Tumor.
Cassette E8:	Section from the dome.
Cassette E9:	Section from the irregular area of the trigone.
Cassettes E10-E11:	Section from the right lateral wall of the urinary bladder.
Cassettes E12-E15:	Slices through the mid part of the prostate, including the right anterior and posterior and left anterior and posterior parts of the prostate, respectively.
Cassettes E16-E19:	Slice from the distal part of the prostate, including the right anterior and posterior and the left anterior and posterior sections, respectively.
Cassette E20:	Right seminal vesicle.
Cassette E21:	Left seminal vesicle.
Cassette E22:	Fibroadipose tissue attached to the outer surface of the urinary bladder.

Part F is additionally labeled "right pelvic lymph nodes." It consists of multiple pieces of fatty tissue, measuring 5.0 x 5.0 x 1.2 cm in aggregate. Multiple tan-pink, soft lymph nodes, ranging in size from 0.3 cm to 0.7 cm, are identified. Some of these are submitted for frozen section, with the frozen section remnant submitted in cassette F1. Additional lymph nodes are identified and are submitted in cassettes F2 and F3.

Part G is additionally labeled "7 - right pelvic lymph node." It consists of one irregular, ovoid, unoriented fragment soft, brown-tan, glistening fibrofatty tissue, measuring 2.0 x 2.0 x 0.2 cm. It has four attached white, metal clips, which are removed. The specimen is entirely submitted, intact, in cassette G1.

Part H is additionally labeled "8 - final left ureter." It consists of two irregular, unoriented fragments soft, pink-tan, glistening fibrous tissue. The larger fragment has two attached white, metal clips and one set of white sutures that are grossly apparent retraction aid. The sutures and clips are removed. The specimen measures 1.7 x 1.0 x 0.3 cm in aggregate. The larger fragment is bisected, and the specimen is entirely submitted in cassette H1.

Part I is additionally labeled "9 - final right ureter." It consists of two irregular, unoriented fragments of firm, pink-tan, glistening fibrous tissue. The larger fragment has one attached white, metal clip and one set of white sutures that are grossly apparent retraction aids. The metal clip is removed. The specimen

[page 4 of 4]
measures 2.0 x 0.8 x 0.8 cm in aggregate. The larger fragment is bisected, and the specimen is entirely submitted in cassette I1.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

Source: NCI Genomic Data Commons file 175f23e8-5252-4a58-a072-44abbbe80b4c (TCGA-UY-A78L.34137AE9-26C3-4CCC-8172-C8DEDF9689A7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).